Gene-level copy-number profile of tumor specimen ALCH-B04K-TTP1-A from ALCHEMIST case ALCH-B04K, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 72.8 years (26,583 days).
Specimen ALCH-B04K-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0f715927-2623-4282-afa1-b938311e7beb.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B04K-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,232 have no estimate.
https://portal.gdc.cancer.gov/files/a03af927-81c5-4a68-af25-71251ece282e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 91; copy number 1: 10,741; copy number 2: 47,112; copy number 3: 424; copy number 4: 21; copy number 5: 1; copy number 6: 1.

Homozygous deletions (total copy number 0; autosomes only): 91 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:232,456,125–232,460,753, 1 gene: ALPI.
- chr3:126,481,166–126,517,773, 1 gene: UROC1.
- chr3:126,526,999–126,558,965, 1 gene (within-gene range 0–1): C3orf22.
- chr4:8,959,628–8,963,981, 1 gene: UNC93B8.
- chr7:5,526,409–5,606,655, 4 genes (within-gene range 0–2): ACTB, AC006483.2, AC006483.1, FSCN1.
- chr8:142,611,049–142,614,479, 1 gene: ARC.
- chr9:61,190,003–61,453,030, 7 genes: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P.
- chr9:61,615,835–61,642,494, 2 genes: FAM242D, Y_RNA.
- chr9:61,665,579–61,666,386, 1 gene: AL935212.2.
- chr11:63,998,558–64,166,113, 5 genes (within-gene range 0–2): MACROD1, AP000721.2, AP006333.2, FLRT1, AP006333.1.
- chr12:38,155,476–38,167,631, 3 genes: AC079460.2, RNA5SP358, RNA5SP359.
- chr14:18,555,677–18,637,421, 10 genes: CR383656.10, CR383656.7, CR383656.13, CR383656.9, OR11H12, CR383656.6, ARHGAP42P5, LINC02297, CR383656.1, CR383656.12.
- chr14:99,583,017–99,680,569, 3 genes (within-gene range 0–2): Y_RNA, AL160313.1, HHIPL1.
- chr15:25,169,337–25,225,284, 31 genes (within-gene range 0–1): DMAC1P1, SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30.
- chr16:2,047,967–2,097,026, 4 genes (within-gene range 0–4): TSC2, MIR1225, AC009065.2, AC009065.5.
- chr17:142,789–386,254, 5 genes (within-gene range 0–1): DOC2B, LINC02091, RPH3AL, AC129507.4, AC129507.1.
- chr17:410,325–431,062, 1 gene (within-gene range 0–1): C17orf97.
- chr17:79,132,722–79,136,402, 1 gene (within-gene range 0–2): AC021534.1.
- chr18:14,143,596–14,151,139, 1 gene: AC006557.2.
- chr20:64,080,082–64,101,162, 3 genes (within-gene range 0–1): OPRL1, LKAAEAR1, AL121581.3.
- chr20:64,105,820–64,107,171, 1 gene: NPBWR2.
- chr22:29,705,256–29,731,833, 3 genes (within-gene range 0–2): AC004882.1, AC004882.2, CABP7.
- chr22:48,538,900–48,547,387, 1 gene (within-gene range 0–1): Z84468.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:1,166,932–1,208,962, 1 gene, copy number 5 (within-gene range 4–5): SPON2.
- chr7:158,719,730–158,720,161, 1 gene, copy number 6: AC019084.1.

Autosomal genes at a single copy (total copy number 1): 9,796. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
